Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0I8, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0I8-01A (Primary Tumor).

100-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Patient:

Path: Site Code breast, upper inner quadrant C50.2
CQCF: breast NOS C50.9

1/17/11

lw

Surgical Pathology: Final

Surg Path

CLINICAL HISTORY:

History of recurrent left breast carcinoma with probable involvement of right breast. S/P left MRM and indurated firm area UIQ of right breast on physical exam. Rule out right breast recurrent carcinoma.

GROSS EXAMINATION:

A. "Right breast biopsy", received fresh. Two pieces of tissue measuring 3.6 x 2.1 x 1.5 cm and 2.2 x 1.7 x 0.7 cm. The surgeon has stated the margins on the piece of tissue are not important. Portions of the specimen have been previously submitted for retinoic acid receptors and ER/PR evaluation. Both fragments are composed of firm pink-tan tissue embedded within yellow fibroadipose tissue. Remaining tissue is sectioned and submitted in Blocks A1-A4.

DIAGNOSIS:

A. "RIGHT BREAST BIOPSY":

INFILTRATING DUCTAL CARCINOMA, NSABP AND NUCLEAR GRADE 3, HISTOLOGIC GRADE

3. SURGICAL MARGINS NOT EVALUATED.

Verified by:

(Electronic Signature)

Date Signed:

Source: NCI Genomic Data Commons file fa28cf32-dc61-4f0e-839d-0e4d04b98fd6 (TCGA-B6-A0I8.E958CD3C-EE14-4CE1-B55C-7830E320F6AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).